Somatic mutation profile of tumor specimen TCGA-73-A9RS-01A (aliquot TCGA-73-A9RS-01A-11D-A410-08) from TCGA case TCGA-73-A9RS, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.5 years (15,162 days).
Specimen TCGA-73-A9RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df6491d4-98ff-4a0b-b88d-780b7ca73d11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-A9RS-10A (Blood Derived Normal), aliquot TCGA-73-A9RS-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0aa4fbc1-ec6c-4376-b2c7-5e796584d234

The open-access MAF lists 1,048 somatic variants for this specimen: 797 protein-altering or splice-affecting, 218 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 672, Silent 218, Nonsense Mutation 56, Frame Shift Del 27, Splice Site 27, Intron 14, RNA 11, Splice Region 7, Frame Shift Ins 5, 3'UTR 4, 5'UTR 2, Nonstop Mutation 2.

Variants (750 of 1,048; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894094, CM119686, CM940230, BM1445822, COSV58692144; ClinVar: risk factor / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GCK | c.824G>T p.R275L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.318); catalogued as rs767565869, COSV100357249, COSV60787127; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 21/36 reads (58%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.9676C>T p.Q3226* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101446993; called by muse, mutect2
- ABCB4 | c.3158A>T p.Q1053L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV99711522; called by muse, mutect2, varscan2
- AC144573.1 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); catalogued as COSV100294789; called by muse, mutect2
- ACCSL | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122339; called by muse, mutect2, varscan2
- ACKR1 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.121); catalogued as COSV100929489, COSV100929714; called by muse, mutect2, varscan2
- ACMSD | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99299571; called by muse, mutect2, varscan2
- ACSL6 | c.724G>T p.G242W (on ENST00000379240; = p.G267W on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776448382, COSV99734902; called by muse, mutect2, varscan2
- ACTN3 | c.2602T>C p.Y868H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773610480, COSV100074554; called by muse, mutect2, varscan2
- ACTR3B | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV99754702; called by muse, mutect2, varscan2
- ACTR6 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV51841589, COSV99498833; called by muse, mutect2, varscan2
- ADAMTS1 | c.2773G>T p.G925W | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536638; called by muse, mutect2, varscan2
- ADAMTS14 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100941953, COSV64601045; called by muse, mutect2, varscan2
- ADAMTS20 | c.4517G>T p.G1506V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as rs777380810, COSV101240703; called by muse, mutect2, varscan2
- ADAMTS8 | c.1858del p.R620Gfs*23 | Frame Shift Del (DEL) | VAF 22/127 reads (17%) | catalogued as COSV57291705; called by pindel, varscan2
- ADAMTSL4 | c.668C>A p.T223N | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99648247; called by muse, mutect2, varscan2
- ADGRB1 | c.3419G>A p.C1140Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100030588; called by muse, mutect2
- ADGRB3 | c.3707G>T p.S1236I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs1171002319, COSV99487289; called by muse, mutect2, varscan2
- ADGRV1 | c.3458C>A p.S1153Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101316694; called by muse, mutect2, varscan2
- ADRA2C | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1400501258, COSV100342880; called by muse, mutect2, varscan2
- AFF2 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100651491, COSV60670645; called by muse, mutect2, varscan2
- AFF2 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs1557279044, COSV53986801; called by muse, mutect2, varscan2
- AGBL1 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs779833653, COSV101224420; called by muse, varscan2
- AGXT2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184028; called by muse, mutect2
- AGXT2 | c.614T>A p.L205H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV99184030; called by muse, mutect2, varscan2
- AHCYL1 | c.477G>A p.A159= | Splice Region (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100779699; called by muse, mutect2, varscan2
- AIFM2 | c.446G>C p.G149A | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV100325853; called by muse, mutect2, varscan2
- AKAP12 | c.4054C>A p.H1352N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1414681482, COSV99484692; called by muse, mutect2, varscan2
- AKNA | c.3853G>T p.G1285C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV56338139, COSV99801268; called by muse, mutect2, varscan2
- AKT2 | c.626A>T p.H209L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV100251882; called by muse, mutect2, varscan2
- ALG10B | c.1277G>C p.R426T | Missense Mutation (SNP) | VAF 61/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100440066; called by muse, mutect2, varscan2
- ALLC | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as rs1177992254, COSV52994330, COSV52994675; called by muse, mutect2, varscan2
- ALOX15B | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs143883230, COSV101205742; called by muse, mutect2
- ALPK3 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs116079740; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPL | c.957C>G p.I319M | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.544); catalogued as rs1310593535, COSV100876345; called by muse, mutect2, varscan2
- ANO2 | c.2089C>A p.P697T (on ENST00000356134 / NM_001278597.3; = p.P701T on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100502661; called by muse, mutect2, varscan2
- APLP2 | c.731C>A p.A244E | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV99600185; called by muse, mutect2, varscan2
- ARHGAP29 | c.2277G>T p.L759F | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.838); catalogued as COSV99559242; called by muse, mutect2, varscan2
- ARHGAP32 | c.3203G>T p.G1068V (on ENST00000310343 / NM_001378025.1; = p.G719V on NM_014715.4) | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs750821506, COSV100088652, COSV59854323; called by muse, mutect2, varscan2
- ARHGEF12 | c.1001A>T p.D334V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV100755307; called by muse, mutect2, varscan2
- ARHGEF17 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as rs1247837702, COSV99737206; called by muse, mutect2, varscan2
- ARMC3 | c.1828G>T p.V610F | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.133); catalogued as COSV99959092; called by muse, mutect2, varscan2
- ARMC4 | c.2433A>T p.Q811H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as rs755790914, COSV59458695, COSV59468507; called by muse, mutect2, varscan2
- ARMCX3 | c.1133A>T p.Q378L | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV100362350; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1307T>C p.F436S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1385795277, COSV100772015; called by muse, mutect2, varscan2
- ARMS2 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV101600766; called by muse, mutect2, varscan2
- ASAP1 | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100728054, COSV63053537; called by muse, mutect2, varscan2
- ASB5 | c.575T>A p.I192K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV56673786, COSV99642246; called by muse, mutect2, varscan2
- ASH1L | c.2828A>T p.Q943L | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV100853650; called by muse, mutect2, varscan2
- ASPM | c.7552A>G p.R2518G | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.696); catalogued as COSV99661337; called by muse, mutect2, varscan2
- ASTN1 | c.3437C>G p.P1146R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100708001, COSV100708026; called by muse, mutect2, varscan2
- ASXL3 | c.2497C>A p.L833M | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV99325457; called by muse, mutect2, varscan2
- ATAD2 | c.1520G>T p.G507V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99785510; called by muse, mutect2, varscan2
- ATAD2B | c.2509G>T p.G837W | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99478707; called by muse, mutect2, varscan2
- ATG2A | c.4525C>A p.Q1509K | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV101034940; called by muse, mutect2, varscan2
- ATP10A | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as rs17854738, COSV100791103, COSV63515206; called by muse, mutect2, varscan2
- ATP12A | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54518384; called by muse, mutect2, varscan2
- ATP13A5 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100665886; called by muse, mutect2, varscan2
- ATP1A3 | c.1820G>T p.G607V (on ENST00000545399 / NM_001256214.2; = p.G594V on NM_152296.5) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.274); catalogued as COSV100132638; called by muse, mutect2, varscan2
- ATP2B3 | c.2543G>A p.S848N | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV54845246, COSV99686251; called by muse, mutect2, varscan2
- ATP5MC2 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100101101; called by muse, mutect2
- ATP6V0A4 | c.337A>T p.N113Y | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100023833; called by muse, mutect2, varscan2
- ATP8B4 | c.1955T>C p.L652S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99468070; called by muse, mutect2, varscan2
- AUTS2 | c.2729A>C p.K910T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV100719785, COSV61385730; called by muse, mutect2, varscan2
- AVPR1A | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs747069794, COSV100146936; called by muse, mutect2, varscan2
- B4GALNT2 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs140662851, COSV55925446; called by muse, mutect2, varscan2
- B4GALNT3 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV56759277; called by muse, mutect2, varscan2
- BARD1 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs774251286, COSV53612607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.3113A>G p.K1038R | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99681107; called by muse, mutect2, varscan2
- BHLHE22 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1169031138, COSV100418020; called by muse, mutect2
- BMP6 | c.1133G>C p.S378T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99307597; called by muse, mutect2
- BMPER | c.785G>T p.R262M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV51821252; called by muse, mutect2, varscan2
- BMPR1A | c.1439G>C p.R480P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100923727, COSV64404959; called by muse, mutect2, varscan2
- BNC1 | c.803A>C p.Q268P | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100597566; called by muse, mutect2
- BNC1 | c.674del p.G225Efs*13 | Frame Shift Del (DEL) | VAF 19/137 reads (14%) | catalogued as COSV61757551; called by mutect2, pindel, varscan2
- BRAF | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV99971893; called by muse, mutect2, varscan2
- BRINP1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56294016; called by muse, mutect2, varscan2
- C1GALT1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.035); catalogued as COSV99777677; called by muse, mutect2, varscan2
- C1R | c.232G>T p.D78Y (on ENST00000536053 / NM_001354346.2; = p.D64Y on NM_001733.7) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865046; called by mutect2, varscan2
- C1orf94 | c.1106G>T p.G369V (on ENST00000488417 / NM_001134734.2; = p.G179V on NM_032884.5) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100975293; called by muse, mutect2, varscan2
- C2CD5 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100449131, COSV61727092; called by muse, mutect2, varscan2
- C3 | c.4115A>G p.E1372G | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99837450; called by muse, mutect2, varscan2
- C6orf118 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV100025322; called by muse, mutect2, varscan2
- C6orf15 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99457356; called by muse, mutect2, varscan2
- CA10 | c.272dup p.R92Qfs*47 | Frame Shift Ins (INS) | VAF 35/164 reads (21%) | catalogued as rs1180449128; called by pindel, varscan2
- CA10 | c.266C>A p.T89K | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.61); catalogued as rs144171943; called by muse, varscan2
- CACNA1E | c.4591G>C p.A1531P | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100704950, COSV100705976; called by muse, mutect2, varscan2
- CACNA1S | c.4037C>A p.P1346Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100755361, COSV100755470; called by muse, mutect2, varscan2
- CACNA2D1 | c.2462G>C p.W821S (on ENST00000356253 / NM_001366867.1; = p.W809S on NM_000722.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs1263114425, COSV100667633; called by muse, mutect2, varscan2
- CALCR | c.785C>A p.T262K (on ENST00000649521 / NM_001164737.2; = p.T246K on NM_001742.4) | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100810920; called by muse, mutect2, varscan2
- CAP2 | c.109G>T p.G37C | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs746572986, COSV100012930; called by muse, mutect2, varscan2
- CAVIN4 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV100293457; called by muse, mutect2, varscan2
- CBWD2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 101/191 reads (53%) | catalogued as rs1211268397, COSV99380913; called by muse, mutect2, varscan2
- CBY2 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.9); catalogued as rs574446712, COSV100137915; called by muse, mutect2, varscan2
- CBY2 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100137916, COSV60119956; called by muse, mutect2, varscan2
- CCDC65 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99908288; called by muse, mutect2, varscan2
- CCKBR | c.1065G>A p.W355* | Nonsense Mutation (SNP) | VAF 39/66 reads (59%) | catalogued as rs751887877, COSV100583171, COSV58106937; called by muse, mutect2, varscan2
- CD5L | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100941253; called by muse, mutect2, varscan2
- CDC7 | c.320G>C p.C107S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99320022; called by muse, mutect2, varscan2
- CDH10 | c.1830C>A p.S610R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100049914; called by muse, mutect2, varscan2
- CDH8 | c.1032C>G p.D344E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100184633, COSV100184915; called by muse, mutect2, varscan2
- CDHR2 | c.2414C>T p.P805L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs750735724, COSV99992307; called by muse, mutect2, varscan2
- CDKL2 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV100277253; called by muse, mutect2
- CDRT1 | c.1060A>G p.K354E | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.76); catalogued as COSV99887991; called by muse, mutect2, varscan2
- CEACAM5 | c.1133T>A p.L378H | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99704226; called by muse, mutect2, varscan2
- CELA3A | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99266798; called by muse, mutect2, varscan2
- CENPF | c.5560C>T p.Q1854* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100872088; called by muse, mutect2, varscan2
- CEP162 | c.2813G>C p.R938T | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100003555; called by muse, mutect2, varscan2
- CFAP47 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99936015; called by muse, mutect2, varscan2
- CFAP61 | c.1257C>A p.F419L | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.164); catalogued as COSV99847065; called by muse, mutect2, varscan2
- CFAP65 | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as rs752204587, COSV100446081; called by muse, mutect2, varscan2
- CFH | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.319); catalogued as COSV100661693; called by muse, mutect2, varscan2
- CFHR5 | c.1434C>A p.C478* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV99889988; called by muse, mutect2
- CLBA1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV101121091, COSV101121153; called by muse, mutect2, varscan2
- CLCN1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100578691, COSV58368407; called by muse, mutect2, varscan2
- CLDN20 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.036); catalogued as COSV100905072; called by muse, mutect2, varscan2
- CLEC14A | c.617G>C p.S206T | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100643695; called by muse, mutect2, varscan2
- CLEC9A | c.363A>T p.R121S | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100872894; called by muse, mutect2, varscan2
- CNGB3 | c.2288T>A p.V763E | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100183335; called by muse, mutect2, varscan2
- CNN2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); catalogued as rs370941672; called by muse, mutect2, varscan2
- CNOT2 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as COSV99973291; called by muse, mutect2, varscan2
- CNST | c.1137G>T p.E379D | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100830139; called by muse, mutect2, varscan2
- CNTN3 | c.1716T>A p.S572R | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV99726412; called by muse, mutect2, varscan2
- CNTN5 | c.2285C>A p.P762Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99675448; called by muse, mutect2, varscan2
- COA4 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV100142811; called by muse, mutect2, varscan2
- COG5 | c.2378A>T p.Y793F (on ENST00000347053 / NM_001379512.1; = p.Y814F on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.877); catalogued as COSV99753700; called by muse, mutect2, varscan2
- COL11A1 | c.5221G>C p.E1741Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100618361, COSV62189636; called by muse, mutect2, varscan2
- COL11A1 | c.3953G>T p.G1318V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618364; called by muse, mutect2, varscan2
- COL11A1 | c.3112C>T p.Q1038* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100618366; called by muse, mutect2, varscan2
- COL19A1 | c.3178G>A p.G1060R | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601105, COSV100507807; called by muse, mutect2, varscan2
- COL4A1 | c.2797G>T p.G933C | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011649; called by muse, mutect2, varscan2
- COL6A6 | c.2670G>T p.E890D | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1363120550, COSV100651104; called by muse, mutect2
- COL9A3 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs541706620, COSV100673628; called by muse, varscan2
- COLEC10 | c.501G>T p.K167N | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1247693220, COSV100250978; called by muse, mutect2, varscan2
- COQ7 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV100430593, COSV58582185; called by muse, mutect2, varscan2
- CPEB2 | c.2602G>C p.D868H | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs1241395917, COSV52590663, COSV99470819; called by muse, mutect2, varscan2
- CRAMP1 | c.783G>T p.M261I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as COSV99562329; called by muse, mutect2, varscan2
- CRB1 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV66331547; called by muse, mutect2, varscan2
- CRIP3 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454749341, COSV99240162; called by muse, mutect2, varscan2
- CRISPLD1 | c.477G>T p.R159S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs1316955702, COSV100082575; called by muse, mutect2, varscan2
- CRYBG2 | c.1045G>T p.A349S | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs1260391246; called by muse, mutect2, varscan2
- CSF3R | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100118361; called by muse, mutect2, varscan2
- CSMD1 | c.9439G>T p.E3147* (on ENST00000520002; = p.E3146* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 14/30 reads (47%) | catalogued as rs1211781358, COSV100155120; called by muse, mutect2, varscan2
- CSMD3 | c.10392del p.I3465Ffs*10 (on ENST00000297405 / NM_001363185.1; = p.I3296Ffs*10 on NM_052900.3) | Frame Shift Del (DEL) | VAF 33/70 reads (47%) | catalogued as COSV52108019; called by mutect2, pindel, varscan2
- CSMD3 | c.9945C>A p.F3315L (on ENST00000297405 / NM_001363185.1; = p.F3146L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1470942858, COSV52351338, COSV99851597; called by muse, mutect2, varscan2
- CSMD3 | c.3194-1del p.X1065_splice (on ENST00000297405 / NM_001363185.1; = p.X961_splice on NM_052900.3) | Splice Site (DEL) | VAF 16/49 reads (33%) | catalogued as COSV99834827; called by mutect2, pindel*, varscan2
- CSN2 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100778859; called by muse, mutect2, varscan2
- CTCFL | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99713531; called by muse, mutect2, varscan2
- CTNNA3 | c.119G>C p.C40S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV100373987; called by muse, mutect2, varscan2
- CTNND2 | c.3613C>A p.R1205S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100481721; called by muse, mutect2, varscan2
- CUBN | c.2632A>T p.S878C | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100913749; called by muse, mutect2, varscan2
- CUX2 | c.1927C>G p.P643A | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99921069; called by muse, mutect2, varscan2
- CUX2 | c.3056C>T p.S1019F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV99921072; called by muse, mutect2, varscan2
- CUX2 | c.4025C>G p.P1342R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99921075; called by muse, mutect2, varscan2
- CYP11B1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99455878; called by muse, mutect2
- CYP11B2 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100011484; called by muse, mutect2, varscan2
- DCAF1 | c.2356A>T p.I786F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV100245067; called by muse, mutect2, varscan2
- DCBLD2 | c.1745T>C p.F582S | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as COSV99505380; called by muse, mutect2, varscan2
- DCLK1 | c.546C>A p.F182L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV55201744, COSV99713648; called by muse, mutect2, varscan2
- DCLRE1A | c.1053A>T p.L351F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100800586; called by muse, mutect2, varscan2
- DDX60 | c.4681+1G>C p.X1561_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101190774; called by muse, mutect2, varscan2
- DDX60L | c.2366G>T p.G789V | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs368624817, COSV99487007, COSV99487270; called by muse, mutect2, varscan2
- DENND2A | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.104); catalogued as COSV99327216; called by muse, mutect2, varscan2
- DERL3 | c.257A>G p.E86G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320397; called by muse, mutect2, varscan2
- DIAPH2 | c.2323T>C p.C775R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100236068; called by muse, mutect2, varscan2
- DIAPH2 | c.2324G>T p.C775F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100236070; called by muse, mutect2, varscan2
- DISP3 | c.1914G>T p.K638N | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV99610289; called by muse, mutect2, varscan2
- DLGAP1 | c.1708T>A p.Y570N | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234679; called by muse, mutect2, varscan2
- DNAH11 | c.4865G>C p.R1622P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100181457, COSV60958943; called by muse, mutect2, varscan2
- DNAH3 | c.11981T>C p.I3994T | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs1338723158, COSV99771387; called by muse, mutect2, varscan2
- DNAH8 | c.12790A>G p.R4264G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100547477, COSV59463000; called by muse, mutect2, varscan2
- DNAH9 | c.5768A>G p.E1923G | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99308881; called by muse, mutect2, varscan2
- DNAI4 | c.800+1G>T p.X267_splice | Splice Site (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100925251, COSV64018474; called by muse, mutect2, varscan2
- DNAJA2 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as COSV100398860, COSV100398960; called by muse, mutect2, varscan2
- DOP1B | c.5740T>G p.Y1914D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101215925; called by muse, mutect2, varscan2
- DPH1 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99559747; called by muse, mutect2, varscan2
- DROSHA | c.2863G>T p.D955Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100757867; called by muse, mutect2, varscan2
- DSG3 | c.1687C>A p.H563N | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99934884; called by muse, mutect2, varscan2
- DSG3 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.104); catalogued as rs1430746589, COSV99934887; called by muse, mutect2, varscan2
- DST | c.7501G>A p.G2501S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.017); catalogued as COSV99761073; called by muse, mutect2, varscan2
- DYNLRB1 | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV100307890; called by muse, mutect2, varscan2
- EBF2 | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1159374949, COSV101282308; called by muse, mutect2, varscan2
- ECHDC3 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1351882948, COSV101004520, COSV101004569; called by muse, mutect2, varscan2
- EDIL3 | c.83C>G p.P28R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.281); catalogued as COSV99679778; called by muse, mutect2, varscan2
- EDNRA | c.610A>T p.I204F | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100163707; called by muse, mutect2, varscan2
- EFS | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV99391828; called by muse, mutect2, varscan2
- EGF | c.2329G>T p.G777W | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99491502; called by muse, mutect2, varscan2
- EGFLAM | c.2652del p.M885* (on ENST00000354891 / NM_001205301.2; = p.M877* on NM_152403.4) | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV59292176; called by mutect2, pindel, varscan2
- EGFLAM | c.2899+1del | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs779054196; called by mutect2, pindel, varscan2
- EHBP1L1 | c.4232del p.L1411Rfs*31 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as COSV100442093; called by mutect2, pindel, varscan2
- EHF | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99141109; called by muse, mutect2, varscan2
- EHHADH | c.1934A>T p.H645L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV99213419; called by muse, mutect2
- ELSPBP1 | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100353807; called by muse, mutect2, varscan2
- ENDOU | c.649G>A p.E217K (on ENST00000422538 / NM_001172439.2; = p.E176K on NM_006025.4) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99968409; called by muse, mutect2, varscan2
- ENOSF1 | c.472G>T p.V158L (on ENST00000340116 / NM_001354066.2; = p.V110L on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV99201212; called by muse, mutect2, varscan2
- ENPEP | c.2281T>A p.L761M | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99488309; called by muse, mutect2, varscan2
- EPB41L2 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 74/124 reads (60%) | catalogued as rs1168625576, COSV100441553; called by muse, mutect2, varscan2
- EPB41L3 | c.2307G>T p.R769S | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV100550639; called by muse, mutect2, varscan2
- EPHA5 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as COSV56634688; called by muse, mutect2, varscan2
- EPS8L3 | c.764A>T p.K255M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as COSV100719774; called by muse, mutect2, varscan2
- ERC2 | c.451C>A p.Q151K | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV55648655, COSV99891783; called by muse, mutect2, varscan2
- ERGIC2 | c.336A>T p.T112= | Splice Region (SNP) | VAF 14/128 reads (11%) | catalogued as COSV100792053; called by muse, mutect2, varscan2
- ERICH3 | c.3583G>T p.E1195* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs1282343197, COSV100446123; called by muse, mutect2, varscan2
- ESCO1 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV99332697; called by muse, mutect2, varscan2
- ETNPPL | c.179del p.G60Dfs*12 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | catalogued as COSV56595915; called by mutect2, pindel, varscan2
- EXT2 | c.1225G>A p.A409T (on ENST00000343631; = p.A442T on NM_000401.3) | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100640718; called by muse, mutect2, varscan2
- EZR | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs781182006, COSV99792744; called by mutect2, varscan2
- F13B | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1347771089, COSV66373300, COSV66375186; called by muse, mutect2, varscan2
- FAM107B | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs1422737048, COSV99474663; called by muse, mutect2, varscan2
- FAM114A2 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV100491802; called by muse, mutect2, varscan2
- FAM180A | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100647351; called by muse, mutect2, varscan2
- FAM83B | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761888739, COSV100175205; called by muse, mutect2, varscan2
- FANCM | c.3781G>T p.G1261* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99951832; called by muse, mutect2, varscan2
- FAT3 | c.13129C>G p.Q4377E | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99972461; called by muse, mutect2, varscan2
- FAT4 | c.10950C>A p.H3650Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100630637; called by muse, mutect2, varscan2
- FBN2 | c.1232-1G>T p.X411_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as COSV52544145; called by muse, mutect2, varscan2
- FBXO4 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99715363; called by muse, mutect2
- FBXO41 | c.829G>T p.D277Y | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs560505878, COSV99721712; called by muse, varscan2
- FCRL1 | c.1214A>G p.D405G | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV100839932; called by muse, mutect2, varscan2
- FCRL5 | c.1274C>G p.S425W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100708778, COSV62519819; called by muse, mutect2, varscan2
- FCRLA | c.769C>G p.H257D (on ENST00000367959; = p.H234D on NM_032738.4) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.816); catalogued as COSV99376772; called by muse, mutect2, varscan2
- FERMT1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99452275; called by muse, mutect2, varscan2
- FGD5 | c.2033C>A p.S678Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV53250934, COSV99549633; called by muse, mutect2, varscan2
- FHL5 | c.304T>A p.C102S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100459899; called by muse, mutect2, varscan2
- FILIP1 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 81/152 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV52736696, COSV99386400; called by muse, mutect2, varscan2
- FLG | c.10117C>G p.R3373G | Missense Mutation (SNP) | VAF 161/551 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs574781406, COSV100912444; called by muse, mutect2, varscan2
- FLNC | c.2464A>C p.I822L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV100368981; called by muse, mutect2, varscan2
- FLNC | c.3800G>A p.R1267Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs768767784, COSV100368982, COSV57964023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.2107G>C p.G703R | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99989533; called by muse, mutect2
- FLT4 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56100890; called by muse, mutect2, varscan2
- FMN2 | c.1629G>C p.L543F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100147829; called by muse, mutect2, varscan2
- FMO2 | c.133-1G>T p.X45_splice | Splice Site (SNP) | VAF 36/131 reads (27%) | catalogued as COSV99269396; called by muse, mutect2, varscan2
- FNDC3B | c.1248G>T p.W416C | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100395193; called by muse, mutect2, varscan2
- FOXS1 | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99640383; called by muse, mutect2, varscan2
- FRAS1 | c.2424C>A p.D808E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as rs1341231264, COSV99356709; called by muse, mutect2, varscan2
- FRAS1 | c.6574A>G p.S2192G | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99356710; called by muse, mutect2
- FRAS1 | c.7922A>T p.N2641I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV99356711; called by muse, mutect2
- FREM2 | c.8603A>G p.K2868R | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as rs781161007, COSV99750852, COSV99751552; called by muse, mutect2, varscan2
- FRG2C | c.847T>C p.*283Rext*11 | Nonstop Mutation (SNP) | VAF 22/118 reads (19%) | catalogued as rs1257265281; called by muse, varscan2
- FRMD6 | c.1726G>C p.E576Q (on ENST00000344768 / NM_001267046.2; = p.E568Q on NM_152330.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as COSV100656429; called by muse, mutect2, varscan2
- FYB1 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100686612; called by muse, mutect2, varscan2
- GABPB1 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV99590247; called by muse, mutect2, varscan2
- GABRA2 | c.1059G>A p.K353= | Splice Region (SNP) | VAF 26/49 reads (53%) | catalogued as COSV100734847; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1G>T p.X417_splice (on ENST00000361925 / NM_001375343.1; = p.X377_splice on NM_000816.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100729907; called by muse, mutect2, varscan2
- GAD2 | c.1100G>A p.W367* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV99394288; called by muse, mutect2, varscan2
- GANAB | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100648260; called by muse, mutect2, varscan2
- GAPDHS | c.422A>C p.D141A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.31); catalogued as COSV99722954; called by muse, mutect2, varscan2
- GCKR | c.1847C>A p.P616H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.404); catalogued as rs1234969375, COSV99269554; called by muse, mutect2, varscan2
- GCN1 | c.878G>T p.S293I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100326254; called by muse, mutect2, varscan2
- GDA | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1339889584, COSV52990052; called by muse, mutect2, varscan2
- GDNF | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100427611; called by muse, mutect2, varscan2
- GFPT1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623039; called by muse, mutect2, varscan2
- GFRA1 | c.334+2T>A p.X112_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100816319; called by muse, mutect2
- GFRA1 | c.133A>G p.K45E | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100816320; called by muse, mutect2, varscan2
- GFRAL | c.343T>C p.W115R | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100476208; called by muse, mutect2, varscan2
- GGTLC1 | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV99601032; called by muse, mutect2, varscan2
- GIGYF2 | c.2614G>T p.A872S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1380191367; called by muse, mutect2
- GJA10 | c.1426C>A p.H476N | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs772503191, COSV65355523; called by muse, mutect2, varscan2
- GLI1 | c.694G>C p.V232L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV99954839; called by muse, mutect2, varscan2
- GLRA3 | c.339C>A p.D113E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs758779867, COSV56858836, COSV99928357; called by muse, mutect2, varscan2
- GMPPB | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as COSV100246793; called by muse, mutect2, varscan2
- GNAS | c.1000G>C p.G334R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.438); catalogued as COSV100008044, COSV58329690; called by muse, mutect2, varscan2
- GNMT | c.248C>A p.T83K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs754730549, COSV99770065; called by muse, mutect2, varscan2
- GPATCH3 | c.611A>T p.E204V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100658942; called by muse, mutect2, varscan2
- GPR141 | c.46G>C p.V16L | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100550519; called by muse, mutect2, varscan2
- GPR45 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV99307304; called by muse, mutect2, varscan2
- GRAMD1B | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100455381; called by muse, mutect2
- GRIK2 | c.1096-2A>G p.X366_splice | Splice Site (SNP) | VAF 22/40 reads (55%) | catalogued as rs1436195117, COSV100030159; called by muse, mutect2, varscan2
- GRIK3 | c.1530+1G>T p.X510_splice | Splice Site (SNP) | VAF 10/28 reads (36%) | catalogued as COSV100902481; called by muse, mutect2, varscan2
- GRIK3 | c.834C>A p.N278K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100902483; called by muse, mutect2, varscan2
- GRIN2B | c.3508G>C p.G1170R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.049); catalogued as COSV101663237; called by muse, mutect2, varscan2
- GRM2 | c.1859C>G p.T620S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99623268; called by muse, mutect2, varscan2
- GRM8 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100286889; called by muse, mutect2, varscan2
- GUCY1A1 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 19/43 reads (44%) | catalogued as rs1420954133, COSV99638900; called by muse, mutect2, varscan2
- GZMK | c.356T>A p.L119Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99141063; called by muse, mutect2, varscan2
- H4C6 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs758449879, COSV100897515; called by muse, mutect2, varscan2
- HAGHL | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV52405908, COSV99284623; called by muse, mutect2, varscan2
- HAVCR2 | c.205A>T p.R69W | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV100325059; called by muse, mutect2, varscan2
- HCK | c.627C>G p.Y209* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV99394732; called by muse, mutect2, varscan2
- HECW1 | c.2507A>G p.E836G | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1484887828, COSV101224415; called by muse, mutect2, varscan2
- HECW1 | c.4033G>T p.G1345C | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67833644; called by muse, mutect2, varscan2
- HECW1 | c.4034G>T p.G1345V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV67836969; called by muse, mutect2, varscan2
- HECW2 | c.4523A>G p.Y1508C | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99649466; called by muse, mutect2, varscan2
- HEPACAM2 | c.1318C>A p.Q440K (on ENST00000394468 / NM_001039372.4; = p.Q428K on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1251468693, COSV100506863; called by muse, mutect2, varscan2
- HEPH | c.1642G>A p.D548N (on ENST00000343002; = p.D281N on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100295986; called by muse, mutect2
- HFM1 | c.20G>C p.C7S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV99647076; called by muse, mutect2
- HGF | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV55955475, COSV99738895; called by muse, mutect2, varscan2
- HGFAC | c.1927G>A p.D643N | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs868141481, COSV66977460; called by muse, mutect2, varscan2
- HIVEP2 | c.2855G>T p.G952V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99176922; called by muse, mutect2, varscan2
- HMCN1 | c.16682G>A p.G5561E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99637656; called by muse, mutect2, varscan2
- HMGCS2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs145633208; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.650G>T p.G217V (on ENST00000354667 / NM_031243.3; = p.G205V on NM_002137.4) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as COSV100523037; called by muse, mutect2, varscan2
- HNRNPU | c.1342G>T p.G448C (on ENST00000283179; = p.G510C on NM_004501.3) | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99310804; called by muse, mutect2, varscan2
- HOXD9 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV99982420; called by muse, mutect2, varscan2
- HPDL | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1468417154, COSV100588241; called by muse, mutect2, varscan2
- HSPA12A | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs782327414, COSV100980021; called by muse, mutect2, varscan2
- HSPA6 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs758292053, COSV100554207, COSV100554390; called by muse, varscan2
- HSPB3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1209468323, COSV100116041; called by muse, mutect2, varscan2
- HTRA4 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1443834652, COSV100206033; called by muse, mutect2, varscan2
- ICE2 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as rs1169992176, COSV99831921; called by muse, mutect2, varscan2
- IFNLR1 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100552349; called by muse, mutect2, varscan2
- IFNLR1 | c.957G>C p.K319N | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV100552353; called by muse, mutect2, varscan2
- IFT172 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753783467, COSV53134395; called by muse, mutect2, varscan2
- IGFBP2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV52079474; called by muse, mutect2
- IGSF9 | c.1499A>G p.N500S (on ENST00000368094 / NM_001135050.2; = p.N484S on NM_020789.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV100829674; called by muse, mutect2, varscan2
- IKZF4 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV56272606; called by muse, mutect2, varscan2
- IL37 | c.620G>T p.C207F | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.143); catalogued as COSV99636650; called by muse, mutect2, varscan2
- IMPG1 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs1266405696, COSV100886780, COSV64060393; called by muse, mutect2, varscan2
- INSR | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100253848; called by muse, mutect2, varscan2
- INSRR | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948248; called by muse, mutect2, varscan2
- INTS3 | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.143); catalogued as COSV100016660; called by muse, mutect2, varscan2
- INTS6L | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 84/123 reads (68%) | catalogued as COSV100878362, COSV66083878; called by muse, mutect2, varscan2
- IQCB1 | c.1130-1G>T p.X377_splice | Splice Site (SNP) | VAF 26/122 reads (21%) | catalogued as CS119619, COSV100182204; called by muse, mutect2, varscan2
- IQGAP1 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99185481; called by muse, mutect2, varscan2
- ITGA11 | c.1252C>A p.L418I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100242374; called by muse, mutect2, varscan2
- ITPR2 | c.7254G>T p.K2418N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV67276954; called by muse, mutect2
- ITPR3 | c.7249G>T p.G2417* | Nonsense Mutation (SNP) | VAF 20/36 reads (56%) | catalogued as COSV100953686; called by muse, mutect2, varscan2
- ITPRID2 | c.3244A>T p.K1082* | Nonsense Mutation (SNP) | VAF 48/66 reads (73%) | catalogued as COSV100238895, COSV57470682; called by muse, mutect2, varscan2
- IVL | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100908312; called by muse, mutect2, varscan2
- JPH1 | c.1693G>T p.V565L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100646837, COSV60608415; called by muse, mutect2, varscan2
- KCMF1 | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.626); catalogued as COSV101301294; called by muse, mutect2, varscan2
- KCNA5 | c.1280T>C p.L427S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99364302; called by muse, mutect2, varscan2
- KCNB1 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV100870613; called by muse, mutect2, varscan2
- KCNB2 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101579037; called by muse, mutect2, varscan2
- KCNH4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99238055; called by muse, mutect2, varscan2
- KCNH5 | c.1907G>C p.C636S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100528533; called by muse, mutect2, varscan2
- KCNIP1 | c.196G>T p.V66F (on ENST00000411494 / NM_001034837.3; = p.V55F on NM_014592.4) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs1353863535, COSV100200283; called by muse, mutect2, varscan2
- KCNK13 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as COSV56412695; called by muse, mutect2, varscan2
- KCNQ1 | c.1393G>T p.V465L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.407); catalogued as COSV99328931; called by muse, mutect2, varscan2
- KCNT1 | c.2577C>A p.D859E (on ENST00000488444; = p.D878E on NM_020822.3) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV99707070; called by muse, mutect2, varscan2
- KCNT2 | c.1404-1G>A p.X468_splice | Splice Site (SNP) | VAF 10/99 reads (10%) | catalogued as COSV99657566; called by muse, mutect2
- KCTD19 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100431314; called by muse, mutect2, varscan2
- KCTD8 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.04); catalogued as COSV100760248; called by muse, mutect2, varscan2
- KDM3A | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 58/120 reads (48%) | catalogued as COSV100461145; called by muse, mutect2, varscan2
- KHDC3L | c.169+1G>T p.X57_splice | Splice Site (SNP) | VAF 24/41 reads (59%) | catalogued as COSV100951176; called by muse, mutect2, varscan2
- KHDC4 | c.1624G>T p.G542W | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100851042; called by muse, mutect2, varscan2
- KIAA0825 | c.356G>T p.W119L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100265596; called by muse, mutect2
- KIAA1210 | c.3748G>C p.G1250R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV101274464; called by muse, mutect2, varscan2
- KIAA1522 | c.1148C>T p.P383L (on ENST00000373480 / NM_001198972.2; = p.P442L on NM_020888.3) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765046369, COSV53865793, COSV99615303; called by muse, mutect2, varscan2
- KIAA1549L | c.5460C>A p.N1820K (on ENST00000321505; = p.N2117K on NM_012194.3) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100382633; called by muse, mutect2, varscan2
- KIAA2026 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | catalogued as COSV101199257; called by muse, mutect2, varscan2
- KIF1C | c.1569C>T p.T523= | Splice Region (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100297338; called by muse, mutect2, varscan2
- KIR2DL3 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1398846931; called by muse, mutect2, varscan2
- KL | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101199252; called by muse, mutect2, varscan2
- KLF11 | c.1129A>C p.T377P | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100007977; called by muse, mutect2, varscan2
- KLHL13 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99452795; called by muse, mutect2, varscan2
- KLK15 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100033100; called by muse, mutect2, varscan2
- KMT2C | c.11844G>T p.Q3948H | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV100078105, COSV51487532; called by muse, mutect2, varscan2
- KMT2C | c.3323G>A p.R1108K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100078108, COSV51448117; called by muse, mutect2, varscan2
- KMT2C | c.2436G>T p.M812I | Missense Mutation (SNP) | VAF 30/271 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100078110, COSV51504156; called by muse, mutect2, varscan2
- KNDC1 | c.1693C>A p.R565S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs144567158; called by muse, varscan2
- KREMEN1 | c.365G>T p.C122F (on ENST00000407188; = p.C124F on NM_032045.5) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100588860; called by muse, mutect2, varscan2
- KRT33B | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs778321700, COSV99290902; called by muse, mutect2, varscan2
- KRT34 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs748179071, COSV101222743, COSV67450622; called by muse, mutect2, varscan2
- KRT74 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 56/178 reads (31%) | catalogued as COSV99977731; called by muse, mutect2
- KRT82 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as COSV57786619, COSV99233860; called by muse, mutect2, varscan2
- KRTAP13-3 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV100481872; called by muse, varscan2
- KRTAP13-3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV61880521; called by muse, varscan2
- KTI12 | c.890T>C p.L297S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV100860290; called by muse, mutect2, varscan2
- LCE2A | c.232C>A p.H78N | Missense Mutation (SNP) | VAF 68/160 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.325); catalogued as COSV100909171, COSV100909227; called by muse, mutect2, varscan2
- LCK | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100288261; called by muse, mutect2
- LILRA1 | c.1390C>G p.R464G | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV99252334; called by muse, mutect2, varscan2
- LILRA4 | c.1447A>T p.S483C | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99393475; called by muse, mutect2, varscan2
- LIPA | c.895-2A>T p.X299_splice | Splice Site (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100290455; called by muse, mutect2, varscan2
- LIPK | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV101345002; called by muse, mutect2, varscan2
- LIX1L | c.416A>T p.Y139F | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV100995879; called by muse, mutect2, varscan2
- LRCH2 | c.1649G>T p.S550I | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.059); catalogued as COSV100407805; called by muse, mutect2, varscan2
- LRFN5 | c.851G>T p.C284F | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99985870; called by muse, mutect2, varscan2
- LRIT1 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs1440737362, COSV100813008; called by muse, mutect2
- LRP1B | c.11353G>T p.D3785Y | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.883); catalogued as COSV101262175, COSV67234387; called by muse, mutect2, varscan2
- LRP1B | c.4461G>T p.W1487C | Missense Mutation (SNP) | VAF 72/113 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101262176; called by muse, mutect2, varscan2
- LRP2 | c.7224T>A p.H2408Q | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV99790787; called by muse, mutect2, varscan2
- LRRC34 | c.640C>G p.L214V | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.199); catalogued as COSV100336469; called by muse, mutect2, varscan2
- LRRC40 | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs1346885549, COSV100918861, COSV100918878; called by muse, mutect2, varscan2
- LRRC41 | c.787T>G p.C263G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100586599; called by muse, mutect2, varscan2
- LRRC7 | c.1142G>A p.S381N (on ENST00000651989 / NM_001370785.2; = p.S348N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.091); catalogued as rs1172629412, COSV99230581; called by muse, mutect2, varscan2
- LRRC7 | c.3166C>G p.Q1056E (on ENST00000651989 / NM_001370785.2; = p.Q1023E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV99230583; called by muse, mutect2, varscan2
- LRRIQ3 | c.525A>T p.K175N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV100599601; called by muse, mutect2, varscan2
- LRRK2 | c.3481A>G p.R1161G | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs750727045, COSV100111468; called by muse, mutect2, varscan2
- LSS | c.1011G>T p.P337= | Splice Region (SNP) | VAF 14/31 reads (45%) | catalogued as rs759946114, COSV100711060, COSV100711091; called by muse, mutect2, varscan2
- LYAR | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100603572; called by muse, mutect2, varscan2
- LYST | c.10816A>T p.M3606L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs1308859528, COSV101090498; called by muse, mutect2, varscan2
- MADD | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100212147; called by muse, mutect2
- MAGEC2 | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV56001730; called by muse, mutect2, varscan2
- MAGIX | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 34/44 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100891950; called by muse, mutect2, varscan2
- MAML1 | c.1107G>C p.Q369H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.142); catalogued as COSV99483544; called by muse, mutect2, varscan2
- MAML3 | c.1858G>T p.V620L | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100505591; called by muse, varscan2
- MAN2A1 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99812105; called by muse, mutect2
- MAP4K2 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99581945; called by muse, mutect2, varscan2
- MAPK1 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); catalogued as COSV99308269; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3716T>A p.V1239E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99169941; called by muse, mutect2, varscan2
- MAPT | c.1516G>T p.V506L (on ENST00000262410 / NM_001377265.1; = p.V431L on NM_016835.4) | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99291562; called by muse, mutect2, varscan2
- MARCHF11 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV100198334; called by muse, mutect2
- MARK2 | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 43/83 reads (52%) | catalogued as COSV100159256; called by muse, mutect2, varscan2
- MBD5 | c.4168T>G p.W1390G | Missense Mutation (SNP) | VAF 66/101 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101290303; called by muse, mutect2, varscan2
- ME1 | c.1466T>A p.V489E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761842278, COSV100866730; called by muse, mutect2, varscan2
- MED13L | c.4429G>C p.D1477H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV99930568; called by muse, varscan2
- MED14 | c.3590G>T p.G1197V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV100247690; called by muse, mutect2, varscan2
- MESP2 | c.959T>A p.L320Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.36); catalogued as COSV100510889; called by muse, mutect2, varscan2
- MFAP1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV99980211; called by muse, mutect2, varscan2
- MFGE8 | c.1097A>T p.Y366F | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99183990; called by muse, mutect2, varscan2
- MFN2 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99337183; called by muse, mutect2, varscan2
- MGAM | c.776C>A p.P259H | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101516581; called by muse, mutect2, varscan2
- MGAT5B | c.929C>G p.P310R | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049107; called by muse, mutect2, varscan2
- MKI67 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1348493065, COSV100897098; called by muse, mutect2, varscan2
- MMP2 | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99528401; called by muse, mutect2, varscan2
- MMRN2 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV100922698; called by muse, mutect2, varscan2
- MPDZ | c.5016G>T p.W1672C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV59918980; called by muse, mutect2, varscan2
- MROH9 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100883130, COSV63013377; called by muse, mutect2, varscan2
- MSL3 | c.1486G>T p.D496Y (on ENST00000312196 / NM_078629.4; = p.D330Y on NM_006800.4) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100385126; called by muse, mutect2, varscan2
- MSRB3 | c.251A>T p.Y84F | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100378455; called by muse, mutect2, varscan2
- MT1M | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1225727436, COSV101138518; called by muse, mutect2, varscan2
- MTREX | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV100044668; called by muse, mutect2, varscan2
- MTUS2 | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV101462417; called by muse, mutect2, varscan2
- MUC16 | c.2339C>A p.T780K | Missense Mutation (SNP) | VAF 77/119 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as rs1481817133, COSV101202235; called by muse, mutect2, varscan2
- MUC17 | c.11619C>A p.S3873R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100075602; called by muse, mutect2, varscan2
- MVP | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV100651785; called by muse, mutect2, varscan2
- MYH11 | c.2118A>C p.E706D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV100260566; called by muse, mutect2, varscan2
- MYH8 | c.1010G>T p.S337I | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.396); catalogued as COSV101239001; called by muse, mutect2, varscan2
- MYL1 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT tolerated, low confidence (0.07); catalogued as COSV100751782; called by muse, mutect2, varscan2
- MYLK2 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1287610247, COSV101044988; called by muse, mutect2, varscan2
- MYO16 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1282085082, COSV99194984; called by muse, mutect2, varscan2
- MYO16 | c.2587G>T p.E863* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99194989; called by muse, mutect2, varscan2
- MYPN | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.36); catalogued as rs749986338, COSV100590762; called by muse, mutect2
- NALCN | c.2444C>A p.A815E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51926573; called by muse, mutect2
- NALCN | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51951188; called by muse, mutect2, varscan2
- NAV2 | c.1016C>T p.S339L (on ENST00000396087 / NM_001244963.2; = p.S316L on NM_145117.5) | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100587355; called by muse, mutect2, varscan2
- NAV2 | c.2542G>T p.A848S (on ENST00000396087 / NM_001244963.2; = p.A825S on NM_145117.5) | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.831); catalogued as COSV100587356, COSV62316925; called by muse, mutect2, varscan2
- NAV3 | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV99896917; called by muse, mutect2, varscan2
- NAV3 | c.3992C>G p.S1331C | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs771780260, COSV57096731, COSV99896922; called by muse, mutect2, varscan2
- NEO1 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252153400, COSV99981033; called by muse, mutect2, varscan2
- NINL | c.3834T>A p.D1278E | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99626618; called by muse, mutect2, varscan2
- NIPSNAP2 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV100436835; called by muse, mutect2, varscan2
- NLRP2 | c.1995T>A p.N665K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs989447661, COSV54752393, COSV99672740; called by muse, mutect2, varscan2
- NLRP5 | c.402C>A p.N134K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as COSV101173981; called by muse, mutect2, varscan2
- NLRP7 | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100053507, COSV60176547; called by muse, mutect2, varscan2
- NME8 | c.33G>C p.Q11H | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV99554003; called by muse, mutect2, varscan2
- NOTCH4 | c.5252G>C p.R1751P | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV100901238; called by muse, mutect2, varscan2
- NPAP1 | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 93/165 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.059); catalogued as COSV100276390, COSV61508540; called by muse, mutect2, varscan2
- NR3C2 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100679967, COSV60988920; called by muse, mutect2, varscan2
- NRG3 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); catalogued as rs1438535960, COSV64581674; called by muse, mutect2, varscan2
- NTRK1 | c.2011A>T p.M671L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs376816422, COSV100693897; called by muse, mutect2, varscan2
- NTRK1 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs764581997, COSV104423323, COSV62323137; called by muse, varscan2
- NTRK3 | c.2395G>C p.V799L (on ENST00000360948 / NM_001012338.2; = p.V785L on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV62317074; called by muse, mutect2, varscan2
- NWD1 | c.895C>A p.R299S | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.598); catalogued as rs775286731, COSV100343969, COSV60348208; called by muse, mutect2, varscan2
- NYAP2 | c.1114A>T p.M372L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1447571353, COSV99798981; called by muse, mutect2, varscan2
- OCA2 | c.1715G>C p.R572P | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs754265614, COSV100668897, COSV62347287, COSV62347613; called by muse, mutect2, varscan2
- OLFM4 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54576266, COSV99524652; called by muse, mutect2, varscan2
- OPHN1 | c.1103C>A p.P368H | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100830879; called by muse, mutect2, varscan2
- OPLAH | c.2015A>G p.Q672R | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV101471005; called by muse, mutect2, varscan2
- OPN5 | c.918C>A p.Y306* | Nonsense Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99790112; called by muse, mutect2, varscan2
- OPRPN | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as COSV101271114, COSV68192806; called by muse, mutect2, varscan2
- OR10G4 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100305056; called by muse, mutect2, varscan2
- OR10G7 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 85/102 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs764445203, COSV100390124; called by muse, mutect2, varscan2
- OR10G8 | c.607G>T p.G203* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | catalogued as COSV101461900; called by muse, mutect2, varscan2
- OR10Q1 | c.850A>T p.T284S | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV100372436; called by muse, mutect2, varscan2
- OR10X1 | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.965); catalogued as COSV100936724; called by muse, mutect2, varscan2
- OR11A1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101010747; called by muse, mutect2, varscan2
- OR11H4 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100197651; called by muse, mutect2, varscan2
- OR11L1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139127151; called by muse, mutect2, varscan2
- OR11L1 | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100869511; called by muse, mutect2, varscan2
- OR2A2 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV101286689; called by muse, mutect2, varscan2
- OR2G2 | c.776T>A p.I259N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV100190072; called by muse, mutect2, varscan2
- OR2T11 | c.54T>A p.S18R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58185506, COSV58186658; called by muse, mutect2, varscan2
- OR2T12 | c.824T>C p.F275S | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100528067; called by muse, mutect2, varscan2
- OR2T2 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100737829; called by muse, mutect2, varscan2
- OR2T33 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775475303, COSV58813890; called by muse, varscan2
- OR2T34 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100170600; called by muse, mutect2, varscan2
- OR2T4 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 64/373 reads (17%) | catalogued as COSV100822668, COSV63543186; called by muse, mutect2, varscan2
- OR4K15 | c.709C>T p.L237F (on ENST00000305051; = p.L213F on NM_001005486.1) | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as rs767377243, COSV59300231; called by muse, mutect2, varscan2
- OR4K5 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV100262698, COSV60005058; called by muse, mutect2, varscan2
- OR51B4 | c.771C>A p.F257L | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.73); PolyPhen benign (0.162); catalogued as COSV100972239; called by muse, mutect2, varscan2
- OR5B3 | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100512100; called by muse, mutect2, varscan2
- OR5D14 | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV100162685; called by muse, mutect2, varscan2
- OR5K4 | c.565T>A p.C189S | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61583922; called by muse, mutect2, varscan2
- OR5M8 | c.325G>T p.V109F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100510819; called by muse, mutect2, varscan2
- OR5R1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100393628; called by muse, mutect2, varscan2
- OR5T2 | c.969G>T p.L323F | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100507143; called by muse, mutect2, varscan2
- OR6C74 | c.611C>A p.T204K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV100667865, COSV59605845; called by muse, mutect2, varscan2
- OR6M1 | c.287T>G p.M96R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100484225; called by muse, mutect2, varscan2
- OR8K3 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV57132514, COSV57132817, COSV57133068; called by muse, mutect2, varscan2
- OSBPL1A | c.1831G>T p.V611L (on ENST00000319481 / NM_080597.4; = p.V98L on NM_018030.4) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100112996; called by muse, mutect2, varscan2
- OSBPL8 | c.2154G>T p.R718S | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99675761; called by muse, mutect2, varscan2
- OSBPL8 | c.2153G>C p.R718T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99675764; called by muse, mutect2, varscan2
- OSBPL9 | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV100544217; called by muse, mutect2, varscan2
- OTUD7B | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782757919, COSV100967858; called by muse, mutect2, varscan2
- PAPPA2 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100867278; called by muse, mutect2, varscan2
- PAPPA2 | c.2533C>A p.P845T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100867279, COSV62787931; called by muse, mutect2, varscan2
- PAPPA2 | c.4886T>A p.L1629H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV100868824; called by muse, mutect2, varscan2
- PARD3B | c.2815G>T p.G939* (on ENST00000406610 / NM_001302769.2; = p.G870* on NM_057177.7) | Nonsense Mutation (SNP) | VAF 48/108 reads (44%) | catalogued as COSV100595715; called by muse, mutect2, varscan2
- PBX1 | c.940A>T p.T314S | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100905313; called by muse, mutect2, varscan2
- PCDH15 | c.5495C>A p.S1832* | Nonsense Mutation (SNP) | VAF 30/86 reads (35%) | catalogued as COSV100229474; called by muse, mutect2, varscan2
- PCDH15 | c.4923A>T p.Q1641H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV100229479; called by muse, mutect2, varscan2
- PCDH15 | c.2791T>A p.Y931N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100229481; called by muse, mutect2, varscan2
- PCDH15 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100223704, COSV100229488, COSV57408453; called by muse, varscan2
- PCDH15 | c.1045C>A p.L349I | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as COSV100229490; called by muse, mutect2, varscan2
- PCDHA13 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV99170348; called by muse, mutect2, varscan2
- PCDHB7 | c.1690C>A p.P564T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99177603; called by muse, mutect2, varscan2
- PCDHB8 | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); catalogued as COSV99177604; called by muse, mutect2, varscan2
- PCDHB9 | c.1947G>T p.E649D | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV53381124; called by muse, varscan2
- PCDHGA10 | c.1853C>A p.P618Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99549435; called by muse, mutect2, varscan2
- PCDHGB3 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1373345113, COSV99549431; called by muse, mutect2, varscan2
- PCDHGB7 | c.399_400insT p.R134Sfs*4 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | catalogued as COSV99549437; called by mutect2, pindel, varscan2
- PDGFRA | c.1471G>C p.A491P | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.214); catalogued as COSV57265591, COSV99958005; called by muse, mutect2, varscan2
- PDZRN3 | c.2040C>G p.S680R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.826); catalogued as COSV55205979, COSV99732848; called by muse, mutect2, varscan2
- PEG3 | c.566-2A>T p.X189_splice | Splice Site (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99690906; called by muse, mutect2, varscan2
- PGF | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as COSV99462841; called by muse, mutect2, varscan2
- PGK1 | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0.157); catalogued as COSV100540788; called by muse, mutect2, varscan2
- PGM2L1 | c.1703G>C p.R568P | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99995308; called by muse, mutect2, varscan2
- PHLDB2 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as COSV101208793; called by muse, mutect2, varscan2
- PIGC | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV99278465; called by muse, mutect2, varscan2
- PIWIL1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.31); catalogued as COSV55346646, COSV99807047; called by muse, mutect2, varscan2
- PKD1L1 | c.5710C>A p.H1904N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV99221772; called by muse, mutect2
- PKD1L1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV56975849; called by muse, mutect2, varscan2
- PKHD1L1 | c.567G>A p.L189= | Splice Region (SNP) | VAF 7/18 reads (39%) | catalogued as COSV101007132; called by muse, mutect2, varscan2
- PKHD1L1 | c.10384G>T p.G3462W | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101007133; called by muse, mutect2, varscan2
- PLA2G5 | c.168del p.K57Rfs*49 | Frame Shift Del (DEL) | VAF 4/43 reads (9%) | catalogued as rs1557755778; called by mutect2, pindel, varscan2
- PLAT | c.708C>A p.C236* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99535520; called by muse, mutect2, varscan2
- PLCXD3 | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as COSV100125586, COSV100126632; called by muse, mutect2, varscan2
- PLIN1 | c.547A>G p.S183G | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100261801; called by muse, mutect2, varscan2
- PLXNB2 | c.3557G>T p.R1186L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100834376; called by muse, mutect2
- POF1B | c.1436G>C p.R479T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV99427676; called by muse, mutect2, varscan2
- POLB | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1206624667, COSV99613575; called by muse, mutect2, varscan2
- POLRMT | c.335A>T p.K112M | Missense Mutation (SNP) | VAF 60/78 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV101648696, COSV73933100; called by muse, mutect2, varscan2
- POP1 | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62892312, COSV62893554; called by muse, mutect2, varscan2
- POSTN | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); catalogued as COSV65711795; called by muse, mutect2, varscan2
- PPARG | c.131G>C p.G44A (on ENST00000287820 / NM_015869.5; = p.G14A on NM_005037.7) | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV99826901; called by muse, mutect2, varscan2
- PPARGC1A | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 58/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53525915, COSV53529843; called by muse, mutect2, varscan2
- PPFIA4 | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99691168; called by muse, mutect2, varscan2
- PPFIA4 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99691169; called by muse, mutect2, varscan2
- PPIP5K2 | c.2749A>T p.R917* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100384374; called by muse, mutect2, varscan2
- PPP1R16B | c.1323C>A p.N441K | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.243); catalogued as COSV100240253, COSV55376884; called by muse, mutect2, varscan2
- PPP1R3A | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs779545313, COSV52876050, COSV99494765; called by muse, mutect2, varscan2
- PRAMEF15 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1207513893; called by muse, mutect2, varscan2
- PRDM9 | c.1331C>A p.P444Q | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as COSV99691523; called by muse, mutect2, varscan2
- PREPL | c.1822G>T p.G608W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1403251220, COSV99576571; called by muse, mutect2, varscan2
- PRKAA1 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV99713474; called by muse, mutect2, varscan2
- PROX1 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99800417; called by muse, mutect2, varscan2
- PRUNE2 | c.5975G>T p.G1992V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV100945322; called by muse, mutect2, varscan2
- PSPC1 | c.934A>T p.R312W | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.662); catalogued as rs1243380678, COSV100142776; called by muse, mutect2, varscan2
- PSPH | c.353A>G p.H118R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs1339587709, COSV99304689; called by muse, mutect2, varscan2
- PTCHD4 | c.661A>T p.S221C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201108737, COSV100261324, COSV100261970; called by muse, mutect2, varscan2
- PTK2B | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100594553; called by muse, mutect2, varscan2
- PTPRB | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1262595712, COSV99719510; called by muse, mutect2, varscan2
- PTPRC | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100722964, COSV100723335; called by muse, mutect2
- PTPRD | c.2234G>T p.R745I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV100647729; called by muse, mutect2, varscan2
- PTPRD | c.1101C>A p.Y367* | Nonsense Mutation (SNP) | VAF 57/74 reads (77%) | catalogued as COSV100647731; called by muse, mutect2, varscan2
- PTPRN | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99834469; called by muse, mutect2, varscan2
- PYGL | c.2083G>C p.G695R | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369223; called by muse, mutect2, varscan2
- PZP | c.2825C>A p.P942Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54367384; called by muse, mutect2, varscan2
- R3HDML | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.322); catalogued as COSV53836305; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2951A>G p.D984G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.011); catalogued as COSV99770636; called by muse, mutect2, varscan2
- RABL3 | c.13G>C p.D5H | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99382281; called by muse, mutect2, varscan2
- RAD50 | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99529873; called by muse, mutect2, varscan2
- RAD51AP2 | c.1381C>G p.L461V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.215); catalogued as COSV101208434; called by muse, mutect2, varscan2
- RADIL | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101271654; called by mutect2, varscan2
- RAPGEF2 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100031428; called by muse, mutect2, varscan2
- RAPGEF4 | c.2519G>T p.R840L | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217589649, COSV99909308, COSV99911997; called by muse, mutect2, varscan2
- RASA2 | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV53936890, COSV99656908; called by muse, mutect2, varscan2
- RASAL3 | c.2126C>A p.A709D | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV99653966; called by muse, mutect2, varscan2
- RASGEF1B | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100021240, COSV52340132; called by muse, mutect2, varscan2
- RASGRF2 | c.1551+1G>T p.X517_splice | Splice Site (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99430939; called by muse, mutect2, varscan2
- RASSF4 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1350845146, COSV100026684; called by muse, mutect2, varscan2
- RGL1 | c.1328T>G p.I443R (on ENST00000360851 / NM_001297672.2; = p.I478R on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100487955; called by muse, varscan2
- RGPD2 | c.4267G>T p.A1423S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV100553186; called by mutect2, varscan2
- RIC3 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100112466; called by muse, mutect2, varscan2
- RIMBP2 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV55466326, COSV99900903; called by muse, mutect2, varscan2
- RIMS2 | c.1375C>T p.H459Y (on ENST00000666250 / NM_001348490.2; = p.H267Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs560384002, COSV99212891; called by muse, mutect2, varscan2
- RIMS2 | c.2044C>A p.P682T (on ENST00000666250 / NM_001348490.2; = p.P490T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1319892538, COSV99158523, COSV99212914; called by muse, varscan2
- RNF14 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100641327; called by muse, mutect2, varscan2
- RNF150 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100153209; called by muse, mutect2, varscan2
- RNF165 | c.788G>T p.R263M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1183191849, COSV99492196; called by muse, mutect2, varscan2
- ROPN1L | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775309425, COSV99928814; called by muse, mutect2, varscan2
- ROS1 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100877866; called by muse, mutect2, varscan2
- RPAP1 | c.3931C>G p.H1311D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99779399; called by muse, mutect2, varscan2
- RPTN | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 124/310 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV100285910, COSV60167216; called by muse, mutect2, varscan2
- RSAD2 | c.637del p.D213Ifs*8 | Frame Shift Del (DEL) | VAF 33/72 reads (46%) | catalogued as COSV101149792; called by mutect2, pindel, varscan2
- RSPH6A | c.1130T>C p.M377T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1336114179, COSV99680203; called by muse, mutect2
- RTN3 | c.969A>T p.E323D (on ENST00000377819 / NM_001265589.2; = p.E304D on NM_201428.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV100380439; called by muse, mutect2, varscan2
- RUNX1T1 | c.1213G>T p.G405C (on ENST00000265814 / NM_001198628.1; = p.G378C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs745565783, COSV56153354, COSV99755860; called by muse, mutect2, varscan2
- RYR2 | c.4726A>T p.K1576* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100773123; called by muse, mutect2
- RYR2 | c.9908C>T p.S3303F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100773357; called by muse, mutect2, varscan2
- RYR2 | c.14244G>A p.M4748I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100773358; called by muse, mutect2, varscan2
- SAG | c.791C>A p.A264D | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1464600044, COSV101300721; called by muse, mutect2
- SALL3 | c.3501C>G p.N1167K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101610085; called by muse, mutect2
- SATB2 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99613080; called by muse, mutect2, varscan2
- SCAMP3 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV100227002, COSV56944168; called by muse, mutect2, varscan2
- SCARF1 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.608); catalogued as rs1482780644, COSV99557312; called by muse, mutect2, varscan2
- SCGB2A2 | c.41A>T p.Q14L | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99929389; called by muse, mutect2, varscan2
- SCN1A | c.5917A>T p.T1973S (on ENST00000303395 / NM_001202435.3; = p.T1962S on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100322623; called by muse, mutect2, varscan2
- SCN1A | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.979); catalogued as COSV100322625; called by muse, mutect2, varscan2
- SCN7A | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs1474665417, COSV101313159; called by muse, mutect2, varscan2
- SDK1 | c.5074G>T p.V1692L | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.473); catalogued as rs754877724, COSV101270039, COSV67359442; called by muse, mutect2, varscan2
- SELE | c.257C>A p.T86N | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1331265685, COSV100325249; called by muse, mutect2, varscan2
- SENP6 | c.1936A>T p.I646F | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100519635; called by muse, mutect2, varscan2
- SETBP1 | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56319614, COSV99952306; called by muse, mutect2, varscan2
- SGCG | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as rs569816696, COSV99523544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGK2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV58311936; called by muse, mutect2, varscan2
- SH3D19 | c.1876G>A p.E626K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100456001; called by muse, mutect2, varscan2
- SH3RF2 | c.1274C>A p.T425N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100768104; called by muse, mutect2, varscan2
- SH3TC2 | c.529+2T>G p.X177_splice | Splice Site (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100102518; called by muse, mutect2, varscan2
- SHANK1 | c.3513C>A p.S1171R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1303984639, COSV53242852; called by muse, mutect2, varscan2
- SI | c.288G>T p.R96S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.013); catalogued as COSV100017568; called by muse, mutect2
- SI | c.286A>T p.R96W | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100017571; called by muse, mutect2
- SIGLEC1 | c.1137G>T p.L379F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99171514; called by muse, mutect2, varscan2
- SIPA1L3 | c.4903G>T p.D1635Y | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780501745, COSV55910080; called by muse, mutect2, varscan2
- SKAP1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV100412459; called by muse, mutect2
- SLAMF6 | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924967, COSV63586604; called by muse, mutect2, varscan2
- SLC14A2 | c.2746G>C p.A916P | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.439); catalogued as COSV99676333; called by muse, mutect2, varscan2
- SLC16A9 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs757985427, COSV68099433; called by muse, mutect2, varscan2
- SLC16A9 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV101264523; called by muse, mutect2, varscan2
- SLC17A6 | c.1211G>A p.G404D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1363279661, COSV54133968; called by muse, mutect2, varscan2
- SLC18A1 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99369025; called by muse, mutect2, varscan2
- SLC1A1 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99261668; called by muse, mutect2, varscan2
- SLC22A14 | c.465C>A p.C155* | Nonsense Mutation (SNP) | VAF 44/80 reads (55%) | catalogued as rs1203544961, COSV99828406; called by muse, mutect2, varscan2
- SLC22A25 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 74/149 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as COSV100124106; called by muse, mutect2
- SLC27A6 | c.1052G>T p.R351I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321904; called by muse, mutect2, varscan2
- SLC39A12 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1266090678; called by muse, mutect2, varscan2
- SLC44A5 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100902839; called by muse, mutect2, varscan2
- SLC44A5 | c.1291A>G p.K431E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100902840; called by muse, mutect2, varscan2
- SLC4A10 | c.1279C>T p.L427F (on ENST00000446997 / NM_001354461.2; = p.L397F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99766430; called by muse, mutect2, varscan2
- SLC4A8 | c.192C>A p.H64Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV100177723; called by muse, mutect2, varscan2
- SLC4A9 | c.1201C>G p.P401A (on ENST00000507527 / NM_001258428.2; = p.P377A on NM_031467.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV50201009, COSV99140230; called by muse, mutect2, varscan2
- SLC5A8 | c.1710+1G>A p.X570_splice | Splice Site (SNP) | VAF 20/86 reads (23%) | catalogued as COSV101610625; called by muse, mutect2, varscan2
- SLC6A18 | c.604A>T p.I202F | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99722748; called by muse, mutect2, varscan2
- SLC7A13 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99879330; called by muse, mutect2, varscan2
- SLC8A1 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159243625, COSV100247124, COSV100247698; called by muse, mutect2, varscan2
- SLC8A1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100247700; called by muse, mutect2, varscan2
- SLC9C2 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.966); catalogued as COSV100877046; called by muse, mutect2, varscan2
- SLCO1A2 | c.1427G>T p.G476V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1400789002, COSV100262978; called by muse, mutect2, varscan2
- SLIT1 | c.3800C>T p.P1267L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99822836; called by muse, mutect2, varscan2
- SLIT2 | c.1274+1G>T p.X425_splice | Splice Site (SNP) | VAF 31/158 reads (20%) | catalogued as COSV99888192; called by muse, mutect2, varscan2
- SLITRK2 | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100158341; called by muse, mutect2, varscan2
- SLITRK5 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100281338, COSV61523162; called by muse, mutect2, varscan2
- SMARCA4 | c.3547-1G>T p.X1183_splice | Splice Site (SNP) | VAF 34/51 reads (67%) | catalogued as COSV60789409; called by muse, mutect2, varscan2
- SMC2 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.158); catalogued as rs764814020, COSV99659922; called by muse, mutect2, varscan2
- SMC3 | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV100700083; called by muse, mutect2, varscan2
- SMYD3 | c.248A>G p.H83R (on ENST00000490107 / NM_001375962.1; = p.H24R on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101194792; called by muse, mutect2, varscan2
- SNCAIP | c.1940C>A p.A647D | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as COSV54416786; called by muse, mutect2, varscan2
- SORCS1 | c.2774G>T p.W925L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1261040539, COSV99551317; called by muse, mutect2, varscan2
- SP140 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs568864997, COSV100613638; called by muse, mutect2, varscan2
- SPACA3 | c.270C>A p.Y90* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV99284339; called by muse, mutect2, varscan2
- SPACA3 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.238); catalogued as rs765836727, COSV99284340; called by muse, mutect2, varscan2
- SPAG16 | c.1177C>A p.H393N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1379085667, COSV100536649, COSV59075138; called by muse, mutect2, varscan2
- SPATA20 | c.1849G>T p.G617C (on ENST00000356488 / NM_001258372.1; = p.G633C on NM_022827.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV99136930; called by muse, mutect2, varscan2
- SPINDOC | c.763A>T p.T255S | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99588825; called by muse, mutect2, varscan2
- SPRR1A | c.199C>G p.P67A | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100201135; called by muse, mutect2
- SPTBN5 | c.3387G>T p.E1129D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100312446; called by muse, mutect2, varscan2
- SPTSSB | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100780670; called by muse, mutect2, varscan2
- SRSF11 | c.758C>A p.S253* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as rs1206003469, COSV100917901, COSV100918051; called by muse, mutect2, varscan2
- ST14 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.053); catalogued as COSV99599242; called by muse, mutect2
- ST18 | c.1659G>T p.Q553H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV99391428; called by muse, mutect2, varscan2
- STAP1 | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.026); catalogued as rs1253059855, COSV55328214; called by muse, mutect2, varscan2
- STK11 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 19/26 reads (73%) | catalogued as COSV58825370; called by muse, mutect2, varscan2
- STK31 | c.713G>A p.S238N | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs767655035, COSV100670089; called by muse, mutect2, varscan2
- STXBP6 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.29); catalogued as COSV100122335; called by muse, mutect2, varscan2
- SULT1E1 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV56946153, COSV99894745, COSV99895327; called by muse, mutect2, varscan2
- SUPT3H | c.537+1G>T p.X179_splice (on ENST00000371460 / NM_181356.3; = p.X168_splice on NM_003599.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as rs143008476, COSV100178573; called by muse, mutect2, varscan2
- SVEP1 | c.2258G>T p.C753F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1347010865; called by muse, mutect2
- SYMPK | c.2690G>T p.G897V | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99842269; called by muse, mutect2, varscan2
- SYNPO2 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100206596; called by muse, mutect2, varscan2
- TBC1D15 | c.1553-2A>G p.X518_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as rs1354552921, COSV100042385; called by muse, mutect2, varscan2
- TBC1D19 | c.100G>T p.A34S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1238300844, COSV99336916; called by muse, mutect2
- TCERG1L | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100894694; called by muse, mutect2, varscan2
- TCERG1L | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100894696; called by muse, mutect2, varscan2
- TDRD1 | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs1300125431, COSV99315427; called by muse, mutect2, varscan2
- TENT4B | c.2058T>A p.H686Q (on ENST00000561678 / NM_001365323.2; = p.H671Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.198); catalogued as COSV100666208; called by muse, mutect2
- TGFBR3 | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99283880; called by muse, mutect2, varscan2
- TGM1 | c.1369G>T p.V457L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV99253313; called by muse, mutect2, varscan2
- THEMIS2 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100198198; called by muse, mutect2, varscan2
- TINAGL1 | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs552564411, COSV54699084, COSV99593141; called by mutect2, varscan2
- TLCD3B | c.448T>C p.W150R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV99662636; called by muse, mutect2, varscan2
- TLL2 | c.520+1G>T p.X174_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as rs1219276667, COSV100780568; called by muse, mutect2, varscan2
- TLL2 | c.520G>T p.G174W | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755788634, COSV100780569; called by muse, mutect2, varscan2
- TMCO6 | c.357C>G p.S119R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99347452; called by muse, mutect2, varscan2
- TMEFF1 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1266210004, COSV100615122; called by muse, mutect2, varscan2
- TMEM168 | c.1547-2A>T p.X516_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100454856; called by muse, mutect2, varscan2
- TMEM200A | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1012367366, COSV99760305; called by muse, mutect2, varscan2
- TMPRSS15 | c.415G>C p.E139Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.164); catalogued as rs1483638086, COSV99519635; called by muse, mutect2, varscan2
- TMTC2 | c.1489G>T p.G497C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339037; called by muse, mutect2, varscan2
- TNIK | c.2757C>G p.D919E | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV99460407; called by muse, mutect2, varscan2
- TNNI3K | c.2248G>T p.V750L | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV53948487, COSV53953747; called by muse, mutect2, varscan2
- TOPORS | c.2291A>C p.Y764S | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.074); catalogued as rs767534753, COSV100859589; called by muse, mutect2, varscan2
- TPO | c.278T>A p.I93K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV100222503; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1114C>A p.Q372K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.443); catalogued as COSV99163091; called by muse, mutect2, varscan2
- TRDN | c.2091C>A p.Y697* | Nonsense Mutation (SNP) | VAF 8/14 reads (57%) | catalogued as rs749118163, COSV100523696; called by muse, varscan2
- TRIM29 | c.1741G>C p.G581R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV100532114; called by muse, mutect2
- TRIM38 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100837656; called by muse, mutect2, varscan2
- TRPM2 | c.2410C>A p.L804I | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV100309490; called by muse, mutect2, varscan2
- TRPV6 | c.177C>G p.F59L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100844491; called by muse, mutect2, varscan2
- TTC21A | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.873); catalogued as COSV100073372; called by muse, mutect2, varscan2
- TTLL1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.078); catalogued as rs1479384445, COSV99840626; called by muse, mutect2
- TTN | c.86008C>A p.L28670I (on ENST00000591111; = p.L21246I on NM_003319.4) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | PolyPhen probably damaging (0.996); catalogued as rs1218948419, COSV100635641; called by muse, mutect2, varscan2
- TTN | c.21635G>T p.G7212V (on ENST00000591111; = p.G6285V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 111/165 reads (67%) | PolyPhen probably damaging (1); catalogued as rs1194135723, COSV100635643; called by muse, mutect2, varscan2
- TTN | c.3619C>A p.P1207T (on ENST00000591111; = p.P1161T on NM_003319.4) | Missense Mutation (SNP) | VAF 35/91 reads (38%) | PolyPhen possibly damaging (0.797); catalogued as rs373753003; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TYRO3 | c.731C>A p.A244D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1158637569, COSV99778310; called by muse, mutect2, varscan2
- TYRP1 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101141497; called by muse, mutect2, varscan2
- UBD | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100590201; called by muse, mutect2, varscan2
- UBE2E3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101150688; called by muse, mutect2, varscan2
- UBE3C | c.2731G>T p.V911F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61956095; called by muse, mutect2, varscan2
- UBR4 | c.12236G>T p.G4079V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.543); catalogued as COSV100922213; called by muse, mutect2, varscan2
- UBR5 | c.5256A>C p.L1752F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV99642729; called by muse, mutect2, varscan2
- UGT1A4 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100531342; called by muse, mutect2, varscan2
- UGT2B11 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV101485317; called by muse, mutect2, varscan2
- UGT2B7 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100535369, COSV59444974; called by muse, mutect2, varscan2
- ULBP1 | c.616G>T p.D206Y | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99998337; called by muse, varscan2
- UNC13A | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV99409947; called by muse, mutect2, varscan2
- UNC13C | c.1626C>A p.F542L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV52912814, COSV99524343; called by muse, mutect2, varscan2
- UPP1 | c.437-1G>T p.X146_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as rs747942311, COSV100080975; called by muse, mutect2, varscan2
- UQCC1 | c.334-2A>G p.X112_splice | Splice Site (SNP) | VAF 16/105 reads (15%) | catalogued as rs776504493, COSV100568921; called by muse, mutect2, varscan2
- USH2A | c.10822C>G p.L3608V | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100244200; called by muse, mutect2, varscan2
- USH2A | c.5002G>T p.G1668C | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100244201; called by muse, mutect2, varscan2
- USH2A | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.315); catalogued as COSV100244205, COSV56419780; called by muse, mutect2, varscan2
- USO1 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1308911031, COSV99363307; called by muse, mutect2, varscan2
- USP17L2 | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100414808; called by muse, mutect2, varscan2
- USP47 | c.1703G>C p.R568T (on ENST00000399455 / NM_001372095.1; = p.R480T on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100360068; called by muse, mutect2, varscan2
- VIM | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56405279, COSV99813425; called by muse, mutect2
- VWC2L | c.355C>G p.H119D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV100436498, COSV56965208; called by muse, mutect2, varscan2
- WAC | c.135G>C p.K45N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs374702438; called by muse, mutect2, varscan2
- WDFY3 | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99886334; called by muse, mutect2, varscan2
- WDR59 | c.835G>T p.V279L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100049831; called by muse, mutect2, varscan2
- WDTC1 | c.902A>T p.Q301L | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100089675; called by muse, mutect2, varscan2
- WNK1 | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100268936; called by muse, mutect2, varscan2
- XKR4 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.103); catalogued as rs1166450038, COSV100534375; called by muse, mutect2
- XKR7 | c.1434G>C p.R478S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1443913448, COSV101629314, COSV73813455; called by muse, mutect2, varscan2
- XXYLT1 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100118859; called by muse, mutect2, varscan2
- XXYLT1 | c.1017G>C p.M339I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV100118863; called by muse, mutect2, varscan2
- YTHDC2 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1428353295, COSV99364031; called by muse, mutect2, varscan2
- ZBTB20 | c.301G>T p.G101C (on ENST00000474710 / NM_001164342.2; = p.G28C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100615513; called by muse, mutect2, varscan2
- ZC3H7A | c.1719+1G>C p.X573_splice | Splice Site (SNP) | VAF 14/66 reads (21%) | catalogued as COSV100865624; called by muse, mutect2
- ZFHX4 | c.1525C>T p.P509S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV50672530; called by muse, mutect2
- ZMYM1 | c.2379G>T p.R793S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100721113; called by muse, mutect2, varscan2
- ZMYND8 | c.2967G>T p.M989I (on ENST00000311275 / NM_001363741.2; = p.M963I on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs529642788, COSV99521540; called by muse, mutect2, varscan2
- ZNF19 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV99867790; called by muse, mutect2, varscan2
- ZNF222 | c.1037G>A p.C346Y | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99496703; called by muse, mutect2, varscan2
- ZNF281 | c.659A>T p.K220M | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99664594; called by muse, mutect2, varscan2
- ZNF33A | c.1169G>C p.G390A (on ENST00000458705 / NM_006974.3; = p.G391A on NM_006954.2) | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV100275415, COSV100275944; called by muse, mutect2, varscan2
- ZNF347 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100498492; called by muse, mutect2, varscan2
- ZNF415 | c.770C>G p.S257* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV99702151; called by muse, mutect2, varscan2
- ZNF438 | c.1261G>T p.E421* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV100062968; called by muse, mutect2, varscan2
- ZNF454 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as COSV60768801; called by muse, mutect2, varscan2
- ZNF518B | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV58722379; called by muse, mutect2, varscan2
- ZNF521 | c.1734C>G p.N578K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.366); catalogued as COSV100833635; called by muse, mutect2, varscan2
- ZNF521 | c.368G>T p.C123F | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833636; called by muse, mutect2, varscan2
- ZNF536 | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV100836171; called by muse, mutect2, varscan2
- ZNF560 | c.785G>T p.R262M | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV100039173; called by muse, mutect2, varscan2
- ZNF566 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101091664; called by muse, mutect2, varscan2
- ZNF573 | c.1213C>G p.Q405E (on ENST00000536220 / NM_001172692.1; = p.Q347E on NM_152360.3) | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV59828403; called by muse, mutect2, varscan2
298 further variants in this file (47 protein-altering or splice-affecting, 218 silent, 33 other) are not listed here.
